Gene-level copy-number profile of tumor specimen ALCH-B378-TTP1-A from ALCHEMIST case ALCH-B378, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 67.8 years (24,752 days).
Specimen ALCH-B378-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 60a129dc-1e2e-4082-bd45-8d00fd9d80cc.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B378-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,748 have no estimate.
https://portal.gdc.cancer.gov/files/71833059-40f7-4bad-af2e-146ecdab9d60

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 4; copy number 2: 2,889; copy number 3: 5,891; copy number 4: 49,194; copy number 5: 394; copy number 6: 368; copy number 7: 97; copy number 8: 6; copy number 9: 8; copy number 14: 16; copy number 24: 4; copy number 29: 4.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 32 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:12,412,827–12,436,343, 4 genes, copy number 14: AC087203.3, FAM90A25P, ALG1L12P, FAM86B2.
- chr9:61,865,755–61,911,022, 4 genes, copy number 29: AL391987.4, AL391987.3, Y_RNA, FAM242E.
- chr11:65,487,241–65,506,516, 6 genes, copy number 9: LINC02736, AP000769.6, MALAT1, AP000769.2, AP000769.5, AP000769.3.
- chr16:33,140,850–33,570,935, 16 genes, copy number 14–24: ABHD17AP9, AC138869.1, AC138869.2, TP53TG3C, AC138869.3, AC141257.2, TP53TG3E, AC141257.3, TP53TG3B, AC141257.1, AC141257.4, TP53TG3F, AC136944.1, AC136944.2, AC136944.4, AC136944.3.
- chr17:35,540,039–35,540,797, 1 gene, copy number 9: AC015911.2.
- chr18:2,621,090–2,621,201, 1 gene, copy number 9: Y_RNA.

Autosomal genes at a single copy (total copy number 1): 4. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
